Gene-level copy-number profile of tumor specimen ALCH-B2PM-TTP1-A from ALCHEMIST case ALCH-B2PM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.1 years (25,239 days).
Specimen ALCH-B2PM-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 767acf0e-795d-430e-852d-3ad97de292f7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2PM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/c4edf2fd-73c8-4940-bec2-eaee1992cec9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 116; copy number 1: 5,458; copy number 2: 53,139; copy number 3: 197; copy number 4: 3.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,159,751–89,160,366, 1 gene (within-gene range 0–1): IGKV6-21.
- chr2:89,266,494–89,600,680, 9 genes: IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr6:89,950,116–89,953,186, 1 gene (within-gene range 0–2): AL121787.1.
- chr7:62,275,361–63,088,261, 5 genes: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3.
- chr7:140,518,420–140,673,993, 3 genes (within-gene range 0–1): DENND2A, Y_RNA, AC006452.1.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:38,783,004–42,149,549, 2 genes: AL590623.1, KSR1P1.
- chr11:50,307,681–50,422,316, 2 genes: AC024405.2, AC024405.1.
- chr11:54,692,450–54,725,816, 3 genes: OR4A7P, OR4A5, OR4A6P.
- chr12:37,575,587–38,167,631, 7 genes: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359.
- chr16:35,743,268–35,912,516, 21 genes: LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,666. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
